Gene-level copy-number profile of tumor specimen TCGA-BA-A8YP-01A from TCGA case TCGA-BA-A8YP, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 50.3 years (18,355 days).
Specimen TCGA-BA-A8YP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6be871ee-6045-407f-a093-f88a99eb488d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-A8YP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/70d31f16-948e-4fbb-81c8-53071a3e7821

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 1,246; copy number 2: 20,556; copy number 3: 18,954; copy number 4: 10,086; copy number 5: 4,502; copy number 6: 3,676; copy number 7: 287; copy number 8: 332; copy number 9: 38; copy number 10: 5; copy number 11: 6; copy number 13: 30; copy number 15: 33; copy number 16: 7; copy number 23: 4; copy number 49: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-A8YP-01A-11D-A390-01): tumor purity 0.61, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:34,109,560–34,815,325, 1 gene (within-gene range 0–2): PARD3.
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.
- chr14:29,652,809–29,657,916, 1 gene: AL356756.1.
- chr18:14,404,551–15,330,282, 34 genes (within-gene range 0–3): AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 744 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,031,216–120,127,074, 36 genes, copy number 8–16 (within-gene range 3–16): WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P.
- chr2:43,637,260–43,767,987, 1 gene, copy number 15 (within-gene range 2–15): PLEKHH2.
- chr2:43,772,120–43,995,989, 7 genes, copy number 15 (within-gene range 2–15): RN7SKP66, DYNC2LI1, ABCG5, ABCG8, LRPPRC, RNU6-1048P, RN7SL455P.
- chr2:44,921,077–46,187,990, 25 genes, copy number 15 (within-gene range 6–15): LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1, KRTCAP2P1, SIX2, AC093702.1, LINC01121, AC093833.1, AC009236.2, AC009236.1, SRBD1, RN7SL414P, PRKCE, PRKCE-AS1, RPL26P15, AC017006.2.
- chr2:62,069,447–62,533,059, 12 genes, copy number 7 (within-gene range 6–7): AC018462.1, RPSAP26, AC018462.2, B3GNT2, MIR5192, RN7SL51P, AC093159.2, AC093159.1, RN7SL18P, TMEM17, RPL37P13, RPL21P37.
- chr2:62,552,463–62,553,434, 1 gene, copy number 7: PSAT1P2.
- chr2:117,536,387–117,841,658, 4 genes, copy number 8: AC064856.1, AC009312.1, DDX18, AC009404.1.
- chr2:196,638,422–196,809,355, 5 genes, copy number 10: AC068544.2, CCDC150, AC068544.1, GTF3C3, C2orf66.
- chr4:51,843,000–52,551,574, 11 genes, copy number 8: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P.
- chr4:53,459,301–53,701,405, 1 gene, copy number 9 (within-gene range 6–9): LNX1.
- chr4:53,575,713–53,737,156, 3 genes, copy number 9: AC095040.1, LNX1-AS2, AC124017.1.
- chr4:110,794,403–111,552,173, 6 genes, copy number 11: LINC01438, MIR297, LYPLA1P2, AC004062.1, RNU6-289P, AC083795.1.
- chr4:112,145,454–113,384,221, 32 genes, copy number 8–9 (within-gene range 2–9): FAM241A, AC093663.2, AC109347.1, AP1AR, AC109347.2, TIFA, ALPK1, RTEL1P1, TOX4P1, NEUROG2, NEUROG2-AS1, RPL23AP94, ZGRF1, H3P14, LARP7, MIR302CHG, MIR367, MIR302D, MIR302A, MIR302C, MIR302B, OSTCP4, AC106864.1, WRBP1, AC017007.3, Y_RNA, RPL7AP30, AC017007.4, ANK2, AC017007.2, AC017007.5, AC017007.1.
- chr4:113,152,282–113,979,727, 8 genes, copy number 9 (within-gene range 2–9): MIR8082, AC004057.1, RN7SL184P, RNU1-138P, CAMK2D, AC111193.1, ARSJ, AC104779.1.
- chr4:115,920,707–116,952,699, 16 genes, copy number 13: KRT18P21, AC027613.1, EIF3KP3, TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1, AC093765.5, AC093765.4, AC093765.3, AC093765.2, RNU6-119P, AC093765.1.
- chr6:63,193,072–66,094,909, 27 genes, copy number 8: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1.
- chr6:93,240,020–96,521,717, 20 genes, copy number 13–49 (within-gene range 3–49): EPHA7, AL591519.1, AL356094.2, AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36, CYCSP17, MANEA-DT, MANEA, AL607077.1, AL034348.1, KRT18P50, FUT9, UFL1-AS1, RN7SL797P.
- chr7:112,616,440–119,179,149, 88 genes, copy number 8 (broad region; genes not listed).
- chr8:84,162,118–85,540,511, 23 genes, copy number 7 (within-gene range 6–7): TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1.
- chr8:106,697,427–118,111,826, 88 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr11:77,813,319–78,582,156, 29 genes, copy number 8: AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr12:66,767–5,946,232, 138 genes, copy number 7 (broad region; genes not listed).
- chr12:37,575,587–39,619,803, 25 genes, copy number 7 (within-gene range 3–7): ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2.
- chr18:20,946,906–27,247,188, 126 genes, copy number 8 (broad region; genes not listed).
- chr18:27,343,252–27,401,910, 3 genes, copy number 8 (within-gene range 4–8): AC021382.1, UBA52P9, AC068408.1.
- chr18:41,341,319–42,115,538, 8 genes, copy number 8: AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3.
- chr18:42,270,589–42,270,715, 1 gene, copy number 8: RNA5SP454.

Autosomal genes at a single copy (total copy number 1): 706. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
